TCGA case TCGA-GV-A3JX — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - Cleveland Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d9dcbb57-f6c2-4465-8a60-afe876e113ca

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 59.9 years (21,888 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 581 days (1.6 years).
   Pathology details: Consistent pathology review: Yes; Extracapsular extension: Focal; Extracapsular extension present: Yes; Lymph nodes positive: 0; Lymph nodes tested: 27; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 187 days; Disease response: Tumor Free.
- Days to follow up: 581 days (1.6 years); Disease response: Tumor Free.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63.3 kg; Height: 170.2 cm; BMI: 21.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 80; Tobacco smoking quit year: 2009.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GV-A3JX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-GV-A3JX-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-GV-A3JX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GV-A3JX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: cystectomy; Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 581 days; disease-specific survival: no event (censored), 581 days; disease-free interval: no event (censored), 581 days; progression-free interval: no event (censored), 581 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GV-A3JX-01A-11D-A20B-01): tumor purity 0.9, ploidy 1.88, whole-genome doublings 0.
